Somatic mutation profile of cancer-model specimen HCM-BROD-1121-C71-85A (Mixed Adherent Suspension, passage 9; aliquot HCM-BROD-1121-C71-85A-01D-A881-36), derived from the primary tumor of HCMI case HCM-BROD-1121-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.5 years (25,400 days).
Specimen HCM-BROD-1121-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e00a173-12fe-42f1-b65d-5c7ad24318f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-1121-C71-10A (Blood Derived Normal), aliquot HCM-BROD-1121-C71-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf625c9a-a649-4b9b-9506-c7b5b99c98b4

The open-access MAF lists 77 somatic variants for this specimen: 61 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 13, Nonsense Mutation 6, Splice Region 2, Intron 2, Splice Site 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 108/108 reads (100%) | hotspot (GDC flag); catalogued as rs121913303, CM961229, COSV57297124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.2134C>T p.R712* (on ENST00000303395 / NM_001202435.3; = p.R701* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 121/287 reads (42%) | catalogued as rs794726730, CM024300, CX096176, COSV57668399; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 288/290 reads (99%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs876660825, CM161004, COSV52664064, COSV52987047, COSV53313892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQP6 | c.830T>C p.V277A | Missense Mutation (SNP) | VAF 189/399 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs772251291; called by muse, mutect2, varscan2
- CFAP77 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 280/600 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs568452931; called by muse, mutect2, varscan2
- FAM209A | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 229/480 reads (48%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as rs778119401, COSV54766435; called by muse, mutect2, varscan2
- FKBP4 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 175/381 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs927155815, COSV50009374; called by muse, mutect2, varscan2
- HSD17B14 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 112/565 reads (20%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.017); catalogued as rs760796044, COSV54414915; called by muse, mutect2, varscan2
- ICAM5 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 173/415 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1281582816, COSV55746326; called by muse, mutect2, varscan2
- KCNH8 | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 149/329 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.089); catalogued as rs780804433, COSV60465399; called by muse, mutect2, varscan2
- KDR | c.2158C>T p.R720W | Missense Mutation (SNP) | VAF 155/331 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55766144; called by muse, mutect2, varscan2
- KRTAP12-3 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 344/1136 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.904); catalogued as rs200134575; called by muse, mutect2, varscan2
- MAGEB5 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 677/678 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs1194249073; called by muse, mutect2, varscan2
- MAPK15 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 308/635 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs782490052; called by muse, mutect2, varscan2
- MPEG1 | c.748T>C p.F250L | Missense Mutation (SNP) | VAF 161/361 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.393); catalogued as rs984562259; called by muse, mutect2, varscan2
- MROH2A | c.3422G>A p.R1141H | Missense Mutation (SNP) | VAF 266/550 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs752495187; called by muse, varscan2
- NAV2 | c.6424C>T p.R2142C (on ENST00000396087 / NM_001244963.2; = p.R2083C on NM_145117.5) | Missense Mutation (SNP) | VAF 203/435 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775604597; called by muse, mutect2, varscan2
- NOS3 | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 168/669 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.715); catalogued as rs369675314; called by muse, varscan2
- NRXN1 | c.2500C>T p.Q834* | Nonsense Mutation (SNP) | VAF 110/233 reads (47%) | catalogued as COSV100453751; called by muse, mutect2, varscan2
- OR51S1 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 231/433 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as rs776320504, COSV100437302; called by muse, mutect2, varscan2
- PAQR6 | c.609G>A p.R203= (on ENST00000292291 / NM_001272108.2; = p.R97= on NM_024897.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 113/252 reads (45%) | catalogued as COSV52744582; called by muse, mutect2, varscan2
- PIK3R6 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 127/339 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs779211198, COSV61005470; called by muse, mutect2, varscan2
- PRX | c.3421G>A p.A1141T | Missense Mutation (SNP) | VAF 197/826 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs775625331; called by muse, mutect2, varscan2
- PTEN | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 124/127 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV64299225; called by muse, mutect2, varscan2
- PTPRT | c.3073G>A p.V1025I | Missense Mutation (SNP) | VAF 140/294 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as rs758531464, COSV61967363; called by muse, mutect2, varscan2
- RYR2 | c.7234G>A p.G2412R | Missense Mutation (SNP) | VAF 104/239 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550534270, COSV100772934, COSV63696306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SENP2 | c.1445T>C p.V482A | Missense Mutation (SNP) | VAF 95/191 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.138); catalogued as COSV56192704; called by muse, mutect2, varscan2
- SLIT2 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 106/246 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241718567, COSV56589344; called by muse, mutect2, varscan2
- SOHLH1 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 242/484 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.248); catalogued as rs528068735, COSV53681805; called by muse, mutect2, varscan2
- SUN3 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 148/550 reads (27%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); catalogued as rs1366501433; called by muse, mutect2, varscan2
- TRHDE | c.2440C>T p.R814C | Missense Mutation (SNP) | VAF 114/271 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.828); catalogued as rs1565813268; called by muse, mutect2, varscan2
- TSPO | c.183G>A p.G61= | Splice Region (SNP) | VAF 139/304 reads (46%) | catalogued as COSV100289822; called by muse, mutect2, varscan2
- ZBTB20 | c.1451C>G p.T484S (on ENST00000474710 / NM_001164342.2; = p.T411S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 273/532 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.093); catalogued as rs1006124149; called by muse, mutect2, varscan2
- ZNF133 | c.403G>C p.E135Q (on ENST00000316358 / NM_001352454.2; = p.E134Q on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 220/463 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV60366551; called by muse, mutect2, varscan2
- ZNF619 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 144/286 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs374238547; called by muse, mutect2, varscan2
- ZNF836 | c.2363G>A p.R788H | Missense Mutation (SNP) | VAF 94/444 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.903); catalogued as rs529214922, COSV59081864; called by muse, mutect2, varscan2
- ABCA9 | c.3332G>A p.S1111N | Missense Mutation (SNP) | VAF 113/180 reads (63%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ADAR | c.836A>G p.E279G | Missense Mutation (SNP) | VAF 270/571 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ANO10 | c.1345T>C p.S449P | Missense Mutation (SNP) | VAF 180/354 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- CAMSAP3 | c.3089G>A p.R1030Q | Missense Mutation (SNP) | VAF 237/521 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DELE1 | c.1247C>A p.A416D | Missense Mutation (SNP) | VAF 201/436 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DNAH5 | c.7504C>T p.R2502C | Missense Mutation (SNP) | VAF 21/858 reads (2%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- FAM133A | c.661A>T p.K221* | Nonsense Mutation (SNP) | VAF 188/373 reads (50%) | called by muse, mutect2, varscan2
- GAL3ST4 | c.1139G>T p.R380L | Missense Mutation (SNP) | VAF 243/823 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HTT | c.3193G>A p.G1065R | Missense Mutation (SNP) | VAF 170/480 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ID2 | c.349-21_366del p.X117_splice | Splice Site (DEL) | VAF 56/218 reads (26%) | called by mutect2, pindel
- IGKV1-17 | c.206T>A p.L69Q | Missense Mutation (SNP) | VAF 264/573 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KDF1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 262/846 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MAFA | c.939A>C p.K313N | Missense Mutation (SNP) | VAF 294/574 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP1S | c.1453G>C p.E485Q | Missense Mutation (SNP) | VAF 169/875 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MIPOL1 | c.260A>G p.E87G | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- MN1 | c.3503_3505del p.S1168del | In Frame Del (DEL) | VAF 222/550 reads (40%) | called by mutect2, pindel, varscan2
- MSL3 | c.916G>T p.E306* (on ENST00000312196 / NM_078629.4; = p.E140* on NM_006800.4) | Nonsense Mutation (SNP) | VAF 435/438 reads (99%) | called by muse, mutect2, varscan2
- NOX4 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 86/184 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- NR2F2 | c.715A>G p.T239A | Missense Mutation (SNP) | VAF 280/579 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- OSBPL10 | c.818A>T p.Q273L | Missense Mutation (SNP) | VAF 250/580 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PCK1 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 124/237 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RTEL1 | c.2414G>A p.G805E | Missense Mutation (SNP) | VAF 193/385 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SCNN1G | c.1276C>T p.Q426* | Nonsense Mutation (SNP) | VAF 179/376 reads (48%) | called by muse, mutect2, varscan2
- STAT1 | c.1483T>C p.W495R | Missense Mutation (SNP) | VAF 153/335 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TK2 | c.101G>T p.R34L (on ENST00000299697; = p.R90L on NM_004614.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 212/450 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- ADAMTS12 | c.291C>T p.H97= | Silent (SNP) | VAF 172/369 reads (47%) | catalogued as rs755549255; called by muse, mutect2, varscan2
- AMY2B | c.585C>T p.A195= | Silent (SNP) | VAF 266/446 reads (60%) | catalogued as rs749647052; called by muse, mutect2, varscan2
- COL24A1 | c.3435G>A p.K1145= | Silent (SNP) | VAF 159/487 reads (33%) | called by muse, mutect2, varscan2
- FOXA2 | c.456G>A p.R152= (on ENST00000377115 / NM_153675.3; = p.R158= on NM_021784.5) | Silent (SNP) | VAF 253/576 reads (44%) | catalogued as rs200013287; called by muse, mutect2, varscan2
- GATA6 | c.1674C>T p.S558= | Silent (SNP) | VAF 229/480 reads (48%) | called by muse, varscan2
- GLUD2 | c.396C>T p.I132= | Silent (SNP) | VAF 742/759 reads (98%) | catalogued as rs750276701; called by muse, mutect2, varscan2
- ITPRID1 | c.1299G>A p.P433= | Silent (SNP) | VAF 213/646 reads (33%) | catalogued as rs1277567601; called by muse, mutect2, varscan2
- NKX6-3 | c.255G>C p.S85= | Silent (SNP) | VAF 310/623 reads (50%) | called by muse, mutect2, varscan2
- PREP | c.1848G>T p.A616= (on ENST00000369110; = p.A682= on NM_002726.5) | Silent (SNP) | VAF 269/559 reads (48%) | catalogued as COSV100963710; called by muse, mutect2, varscan2
- PSMC2 | c.684A>T p.A228= | Silent (SNP) | VAF 164/581 reads (28%) | catalogued as rs1054191925; called by muse, mutect2, varscan2
- TMEM128 | c.423G>T p.V141= (on ENST00000382753 / NM_001297552.2; = p.V117= on NM_032927.3) | Silent (SNP) | VAF 103/206 reads (50%) | called by muse, mutect2, varscan2
- UQCRC1 | c.1275C>T p.P425= | Silent (SNP) | VAF 204/464 reads (44%) | called by muse, mutect2, varscan2
- XKR7 | c.867C>T p.D289= | Silent (SNP) | VAF 284/615 reads (46%) | catalogued as rs1303010032, COSV73813317; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-18947G>A | Intron (SNP) | VAF 51/109 reads (47%) | called by muse, mutect2, varscan2
- MFRP | chr11:119345502 C>T | 5'Flank (SNP) | VAF 211/456 reads (46%) | catalogued as rs761598566; called by muse, mutect2, varscan2
- ZNF8 | c.66+141G>A | Intron (SNP) | VAF 186/829 reads (22%) | catalogued as rs1179433727; called by muse, mutect2, varscan2
